Somatic mutation profile of tumor specimen TCGA-DX-AB2X-01A (aliquot TCGA-DX-AB2X-01A-11D-A387-09) from TCGA case TCGA-DX-AB2X, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 73.2 years (26,736 days).
Specimen TCGA-DX-AB2X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 797563fd-d783-4c0e-a7e0-c106c921e577.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-AB2X-10A (Blood Derived Normal), aliquot TCGA-DX-AB2X-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c34e4f9-fee2-42de-9cf3-fd26b50435ae

The open-access MAF lists 39 somatic variants for this specimen: 28 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 9, Nonsense Mutation 3, Splice Site 2, RNA 1, Frame Shift Ins 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SHOX | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 32/89 reads (36%) | catalogued as rs137852552, CM971378, COSV100479112; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 18/21 reads (86%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ATRX | c.6092A>T p.E2031V | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100970901, COSV64883384; called by muse, mutect2, varscan2
- BUD23 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as rs782505357, COSV99736671; called by muse, mutect2, varscan2
- CCDC18 | c.2269T>G p.L757V (on ENST00000343253 / NM_001306076.1; = p.L758V on NM_206886.4) | Missense Mutation (SNP) | VAF 104/138 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV100159678; called by muse, varscan2
- CDYL2 | c.29A>G p.E10G | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101629584; called by muse, mutect2
- CFAP47 | c.82C>A p.P28T | Missense Mutation (SNP) | VAF 54/102 reads (53%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.082); catalogued as COSV99934792, COSV99935196; called by muse, mutect2, varscan2
- COL5A3 | c.4241del p.P1414Rfs*46 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as COSV53410357; called by pindel, varscan2
- CPAMD8 | c.3556C>T p.R1186W (on ENST00000651564; = p.R1139W on NM_015692.5) | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs370777148, COSV101488523; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.485G>C p.G162A | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV101012205, COSV65443210; called by muse, mutect2, varscan2
- MAP1A | c.6740T>A p.L2247Q | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.988); catalogued as COSV100288758; called by muse, mutect2, varscan2
- MED14 | c.4348C>T p.P1450S | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as COSV100010416; called by muse, mutect2, varscan2
- MIA2 | c.1559G>C p.G520A | Missense Mutation (SNP) | VAF 30/38 reads (79%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as COSV99697734; called by muse, mutect2, varscan2
- MS4A14 | c.1450A>G p.R484G | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as COSV100280498; called by muse, mutect2, varscan2
- OR6C76 | c.77T>C p.F26S | Missense Mutation (SNP) | VAF 35/41 reads (85%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.636); catalogued as COSV100094114; called by muse, mutect2, varscan2
- PASK | c.3232C>T p.Q1078* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV99299608; called by muse, mutect2
- RET | c.2576C>A p.S859* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100393796, COSV60700656; called by muse, mutect2, varscan2
- TRIM58 | c.1334G>T p.R445L | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV100825132, COSV63569813; called by muse, mutect2, varscan2
- TRPA1 | c.807+2T>A p.X269_splice | Splice Site (SNP) | VAF 18/69 reads (26%) | catalogued as COSV100084362; called by muse, mutect2, varscan2
- TTF1 | c.1984A>C p.S662R | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV100524742; called by muse, mutect2, varscan2
- TTN | c.4736C>A p.A1579D (on ENST00000591111; = p.A1533D on NM_003319.4) | Missense Mutation (SNP) | VAF 3/35 reads (9%) | PolyPhen probably damaging (0.999); catalogued as COSV100617100, COSV59985178; called by muse, mutect2
- ZFHX4 | c.8099A>G p.N2700S | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.653); catalogued as COSV99263712; called by muse, mutect2, varscan2
- ZMYM3 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100077992; called by muse, mutect2, varscan2
- ZNF804A | c.3392T>A p.F1131Y | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100168345; called by muse, mutect2, varscan2
- H1-7 | c.417G>C p.E139D | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.13); PolyPhen benign (0.037); called by mutect2, varscan2
- MRC1 | c.2172A>C p.E724D | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- NF1 | c.6643-24_6660del p.X2215_splice (on ENST00000358273 / NM_001042492.3; = p.X2194_splice on NM_000267.3) | Splice Site (DEL) | VAF 32/51 reads (63%) | called by mutect2, pindel
- PIK3C2G | c.1309dup p.I437Nfs*19 | Frame Shift Ins (INS) | VAF 16/100 reads (16%) | called by mutect2, varscan2
- GLT8D2 | c.207C>A p.I69= | Silent (SNP) | VAF 32/40 reads (80%) | catalogued as COSV100674057; called by muse, mutect2, varscan2
- HIPK4 | c.507C>A p.R169= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99396751; called by muse, varscan2
- MEGF6 | c.1566G>A p.L522= | Silent (SNP) | VAF 22/27 reads (81%) | catalogued as rs1336898915, COSV99620553; called by muse, mutect2, varscan2
- NACC2 | c.1458C>T p.A486= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs754937337, COSV99508431; called by muse, mutect2, varscan2
- SLC26A4 | c.1230G>A p.T410= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs371756312, COSV99707124; called by muse, mutect2, varscan2
- SMURF1 | c.2004G>T p.T668= | Silent (SNP) | VAF 28/38 reads (74%) | catalogued as COSV100705432, COSV62816498; called by muse, mutect2, varscan2
- TF | c.60C>T p.V20= | Silent (SNP) | VAF 24/34 reads (71%) | catalogued as rs756125441, COSV99395952; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNRC6C | c.2226A>G p.V742= | Silent (SNP) | VAF 45/97 reads (46%) | catalogued as COSV100050088; called by muse, mutect2, varscan2
- TRO | c.1332A>G p.L444= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as COSV99436610; called by muse, mutect2, varscan2
- AC244258.1 | n.869T>A | RNA (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- CHD3 | c.4358+223G>T | Intron (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100391292; called by muse, varscan2
